Somatic mutation profile of tumor specimen TARGET-10-PARLMI-09A (aliquot TARGET-10-PARLMI-09A-01D) from TARGET case TARGET-10-PARLMI, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.3 years (485 days).
Specimen TARGET-10-PARLMI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2f5e83fb-28dd-4303-be9d-2b082c221149.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PARLMI-10A (Blood Derived Normal), aliquot TARGET-10-PARLMI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07f5de2c-e4ab-4290-a818-c38a712765fb

The open-access MAF lists 7 somatic variants for this specimen: 2 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Frame Shift Ins 1, Missense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- YJU2 | c.86G>T p.R29L | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV99508192; called by muse, mutect2
- SLC4A1AP | c.1877dup p.L627Vfs*18 | Frame Shift Ins (INS) | VAF 15/112 reads (13%) | called by mutect2, pindel, varscan2
- FSIP2 | c.5274C>T p.L1758= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs951314582; called by muse, mutect2, varscan2
- KDR | c.453C>T p.L151= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as rs746215344, COSV55759511, COSV55776032; called by muse, mutect2, varscan2
- PIEZO1 | c.5848C>T p.L1950= | Silent (SNP) | VAF 5/61 reads (8%) | catalogued as rs1364234897; called by muse, mutect2
- RTL1 | c.1389C>T p.D463= | Silent (SNP) | VAF 18/117 reads (15%) | catalogued as rs966617899, COSV101128303; called by muse, mutect2, varscan2
- LINC00632 | n.104+2072G>T | Intron (SNP) | VAF 11/144 reads (8%) | catalogued as rs1569346369; called by muse, mutect2
